Gene-level copy-number profile of tumor specimen TCGA-CR-5243-01A from TCGA case TCGA-CR-5243, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G3; Age at diagnosis: 51.5 years (18,812 days).
Specimen TCGA-CR-5243-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a409aef4-2da4-434d-9028-7889a23de42f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-5243-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32fbfb01-a21c-4ba4-9c93-ea283e9a500a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,766; copy number 2: 42,690; copy number 3: 4,975; copy number 4: 1,543; copy number 5: 584; copy number 6: 3; copy number 7: 258.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-5243-01A-01D-1510-01): tumor purity 0.81, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 845 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–11,904,446, 242 genes, copy number 5 (broad region; genes not listed).
- chr5:12,574,830–25,324,386, 163 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:28,285,964–45,696,498, 281 genes, copy number 5–7 (broad region; genes not listed).
- chr20:4,721,909–16,580,622, 159 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,379. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
